Somatic mutation profile of tumor specimen 0DI7VC from CCDI case PBBVMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 9.7 years (3,534 days).
Specimen 0DI7VC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9eef2f9-625b-4bf5-a0e0-d7aeb403ca79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0165131e-a2a1-431c-ad21-2f80180e2df3

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDCD1 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 68/901 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.875); catalogued as rs764852072; called by muse, mutect2
- ASAH1 | c.126+553C>T | Intron (SNP) | VAF 39/174 reads (22%) | catalogued as rs1044214925, COSV100025449; called by muse, mutect2, varscan2
- DCHS2 | n.6471C>A | RNA (SNP) | VAF 32/948 reads (3%) | called by muse, mutect2
- PWWP3A | c.1426-14G>A | Intron (SNP) | VAF 46/223 reads (21%) | called by muse, varscan2
